CCDI case PBCLCB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0af0b74d-2066-45d9-a567-ce8dc4c2ae57

Demographics
Sex at birth: female.

Diagnoses (1)
1. Astroblastoma: ICD-O-3 morphology code: 9430/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.3 years (3,413 days).

Biospecimens (3 samples)
- Sample 0DUKGP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUKI8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DUKIO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
